Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7880, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7880-01A (Primary Tumor).

Microscopic

Sections demonstrate a moderately hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. The tumor cells have small, round nuclei with smooth contours. Many have well formed perinuclear halos. There is little atypia. A significant minority of the tumor cells have similar nuclei but lack perinuclear halos. Finally, a small percentage of the nuclei are elongate with fibrillary processes. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

Addendum

MIB-1 reactive cells are present throughout the tumor. A labeling index of 3.1% is calculated, consistent with the low grade histologic features.

Diagnosis

Oligoastrocytoma, lowgrade/grade II, oligodendroglioma predominant

Source: NCI Genomic Data Commons file 03f99105-5039-45d9-b860-961998c7d023 (TCGA-HT-7880.1C00DE9E-C2C1-4B57-B0A1-1F043D9DE032.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).